CCDI case PBCKFB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/0832ebec-94dd-4f6a-9570-97c1e9695865

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.1 years (5,881 days).

Biospecimens (3 samples)
- Sample 0DUHG6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUHGY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUHHV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
